CCDI case PBBHXT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a00e9a78-8613-4510-811e-36300aece98b

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,340 days).

Biospecimens (3 samples)
- Sample 0D94V8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D94V9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D94VA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
